Surgical pathology report (de-identified scan), TCGA case TCGA-TQ-A7RV, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site University of Sao Paulo, specimen TCGA-TQ-A7RV-01A (Primary Tumor).

[page 1 of 2]
Nature of material: Brain

Received on:

Macroscopy:

Received in formalin, 4 irregular fragments of brain parenchyma measuring 3.9 x 2.6 x 2.1 cm. The surface shows aspects of white, hard and congested tissue. To cuts, it is note softened and whitish tissue area. Note: Material fully included for histological analysis.

Microscopy:

Histological sections stained with h & e show fragments neoplasia glial moderately mobile, incorporated in cells rounded mostly with discreet pleomorphism contained isolated on fund fibrillar. Diagnosis:

Surgical resection product of brain lesion:

- Astrocytoma (grade II, according to the classification of OMS, 2007).

PROFESSIONAL PARTICIPANTS OF REPORT

Per TSS, dx discrepancy from
status TCGA tumor to be
oligoastrocytoma, grade II.

IHPAA Discrepancy	☐	☒

[page 2 of 2]
TCGA Pathologic Diagnosis Discrepancy Form 4.05

Study Subject ID:		Person ID:	N/A
Study/Site:	TCGA Brain lower grade glioma -	Age:	N/A
Event:	PathDiscrepancy	Date of Birth:	
Interviewer:		Sex:	M

Tumor Identifier Provided on Initial Case Quality Control Form

Provide the tumor identifier documented on the initial case quality control form for this case.

Pathologic Diagnosis Provided on Initial Pathology Report

Astrocyoma grade II Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.

Histologic features of the sample provided for TCGA, as reflected on the CQCF

Oligoastrocytoma grade II Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form

wrote in TCGA Pathologic Diagnosis Discrepancy Form: "This case was iniatially pathologist. When I reviewed the case, in my opinion, there is an oligodendroglial component".

Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.

Name of TSS Reviewing Pathologist or Biorepository Director

Provide the name of the pathologist who reviewed this case for TCGA.

Source: NCI Genomic Data Commons file b8e7cb40-23b5-44e8-af6e-22cec9e31ec0 (TCGA-TQ-A7RV.5316A44B-CF13-4A3B-AE9D-115383B906E2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).